Somatic mutation profile of tumor specimen TCGA-AQ-A04J-01A (aliquot TCGA-AQ-A04J-01A-02W-A050-09) from TCGA case TCGA-AQ-A04J, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 45.5 years (16,615 days).
Specimen TCGA-AQ-A04J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b37abe51-b52c-4054-ac3b-76d00e62cd1c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AQ-A04J-10A (Blood Derived Normal), aliquot TCGA-AQ-A04J-10A-01W-A055-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2b59b449-e2c8-4b63-9f69-fcd7716292c8

The open-access MAF lists 67 somatic variants for this specimen: 47 protein-altering or splice-affecting, 18 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 18, Nonsense Mutation 3, Splice Site 3, Frame Shift Del 2, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4349A>G p.Y1450C | Missense Mutation (SNP) | VAF 8/116 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52119179, COSV52130109; called by muse, mutect2
- TP53 | c.332T>C p.L111P | Missense Mutation (SNP) | VAF 42/159 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519997, CX942126, COSV52676090, COSV52699193, COSV52985195; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AC008397.2 | c.418T>A p.S140T | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as COSV53206493, COSV53206897; called by muse, mutect2, varscan2
- ADAMTS14 | c.2087C>T p.S696F | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100941222; called by muse, varscan2
- ADGRV1 | c.14131G>A p.E4711K | Missense Mutation (SNP) | VAF 11/175 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.078); catalogued as COSV101315276; called by muse, mutect2
- ALG13 | c.1602-33_1607del p.X534_splice | Splice Site (DEL) | VAF 65/383 reads (17%) | catalogued as COSV52638976; called by mutect2, pindel
- ALMS1 | c.1678C>T p.P560S | Missense Mutation (SNP) | VAF 70/200 reads (35%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.69); catalogued as COSV52509872; called by muse, mutect2, varscan2
- ANO5 | c.2071C>A p.P691T | Missense Mutation (SNP) | VAF 67/350 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.438); catalogued as COSV61081573, COSV61084983; called by muse, mutect2, varscan2
- APTX | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 36/652 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1355291424, COSV58930347; called by muse, mutect2
- ATF5 | c.805A>C p.I269L | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.928); catalogued as COSV100351695; called by muse, mutect2
- ATP1A2 | c.1079A>G p.E360G | Missense Mutation (SNP) | VAF 39/265 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63403732; called by muse, mutect2, varscan2
- CARMIL3 | c.3481G>A p.G1161R | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs761196916, COSV57725346, COSV57726369; called by muse, mutect2, varscan2
- CCDC191 | c.55C>A p.R19S | Missense Mutation (SNP) | VAF 15/221 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.753); catalogued as COSV99846783; called by muse, mutect2
- CCDC73 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 15/247 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as rs1369233068, COSV100066060; called by muse, mutect2
- CLDN20 | c.279G>C p.L93F | Missense Mutation (SNP) | VAF 33/186 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.011); catalogued as COSV65697268; called by muse, mutect2, varscan2
- CYP7B1 | c.533C>A p.A178E | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV59588310; called by muse, mutect2
- ERMP1 | c.1618G>T p.V540F | Missense Mutation (SNP) | VAF 67/426 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV53037463; called by muse, mutect2, varscan2
- EXOC4 | c.2683G>A p.A895T | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99551846; called by muse, mutect2, varscan2
- F5 | c.5509C>T p.Q1837* | Nonsense Mutation (SNP) | VAF 15/208 reads (7%) | catalogued as COSV100888812; called by muse, mutect2
- GZMH | c.659A>T p.N220I | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.092); catalogued as COSV53538240; called by muse, mutect2, varscan2
- ISOC1 | c.802C>T p.Q268* | Nonsense Mutation (SNP) | VAF 30/89 reads (34%) | catalogued as COSV51491772; called by muse, mutect2, varscan2
- JMJD1C | c.949T>A p.S317T | Missense Mutation (SNP) | VAF 26/314 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV67861665; called by muse, mutect2
- KCND1 | c.902G>C p.R301P | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54414146, COSV99501928; called by muse, mutect2, varscan2
- LARP7 | c.227C>A p.S76Y | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60520960; called by muse, mutect2, varscan2
- LRRC4C | c.1165C>G p.P389A | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53425699, COSV53438196; called by muse, mutect2, varscan2
- NIN | c.1118+1G>T p.X373_splice | Splice Site (SNP) | VAF 49/211 reads (23%) | catalogued as rs1359505312, COSV55390183; called by muse, mutect2, varscan2
- OR4A15 | c.107C>T p.T36M | Missense Mutation (SNP) | VAF 31/166 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.907); catalogued as rs199660751, COSV59033672; called by muse, mutect2, varscan2
- OXR1 | c.913A>C p.T305P (on ENST00000442977 / NM_001198532.1; = p.T304P on NM_018002.3) | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV56329097; called by muse, mutect2, varscan2
- PPP1R1A | c.283C>A p.Q95K | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.692); catalogued as COSV54492705; called by muse, mutect2
- PTPRJ | c.3227C>T p.P1076L | Missense Mutation (SNP) | VAF 28/284 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101394187, COSV101395663; called by muse, mutect2
- RASGEF1B | c.1239G>A p.M413I | Missense Mutation (SNP) | VAF 17/192 reads (9%) | SIFT tolerated (0.96); PolyPhen benign (0.001); catalogued as COSV100020828; called by muse, mutect2
- SOBP | c.583G>T p.E195* | Nonsense Mutation (SNP) | VAF 24/162 reads (15%) | catalogued as COSV57997154; called by muse, mutect2, varscan2
- SPATA31D1 | c.2254T>A p.F752I | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV61195703; called by muse, mutect2, varscan2
- STAB1 | c.2736G>C p.M912I | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV58736209; called by muse, varscan2
- SYNGR4 | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61225386; called by muse, mutect2, varscan2
- TBC1D16 | c.1295G>A p.G432E | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.243); catalogued as COSV100187607; called by muse, mutect2
- TSR1 | c.1004A>G p.D335G | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs745709713, COSV52157961; called by muse, mutect2, varscan2
- UBA5 | c.50G>A p.R17Q | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1559985839, COSV53896219; called by muse, mutect2, varscan2
- USP42 | c.3790T>G p.L1264V | Missense Mutation (SNP) | VAF 57/118 reads (48%) | SIFT tolerated (0.47); PolyPhen benign (0.037); catalogued as COSV60360258; called by muse, mutect2, varscan2
- XIRP2 | c.3230A>G p.K1077R (on ENST00000628543; = p.K1252R on NM_152381.6) | Missense Mutation (SNP) | VAF 64/356 reads (18%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.867); catalogued as rs1238068400, COSV54700178; called by muse, mutect2, varscan2
- ZNF518B | c.533A>T p.Q178L | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58722622; called by muse, mutect2, varscan2
- ZNF875 | c.1754G>A p.G585E | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.833); catalogued as rs1206832650, COSV100182972, COSV60990444; called by muse, varscan2
- ZNF878 | c.1361A>T p.K454M | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV72155999; called by muse, mutect2, varscan2
- FOXP4 | c.1196_1197del p.S399Cfs*45 (on ENST00000307972 / NM_001012426.1; = p.S386Cfs*45 on NM_138457.3) | Frame Shift Del (DEL) | VAF 8/47 reads (17%) | called by pindel, varscan2
- GDAP2 | c.1159G>A p.V387I | Missense Mutation (SNP) | VAF 9/216 reads (4%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); called by muse, mutect2
- PEAR1 | c.138del p.F47Sfs*34 | Frame Shift Del (DEL) | VAF 18/123 reads (15%) | called by mutect2, pindel, varscan2
- STXBP1 | c.569_578+7del p.X190_splice | Splice Site (DEL) | VAF 8/44 reads (18%) | called by mutect2, pindel
- AAAS | c.216C>T p.H72= | Silent (SNP) | VAF 12/237 reads (5%) | catalogued as COSV52932954; called by muse, mutect2
- ANP32E | c.273C>G p.T91= | Silent (SNP) | VAF 70/177 reads (40%) | catalogued as COSV58482192; called by muse, mutect2, varscan2
- CRY2 | c.429A>T p.V143= | Silent (SNP) | VAF 25/121 reads (21%) | catalogued as COSV69888552; called by muse, mutect2, varscan2
- DIP2C | c.1473T>C p.N491= | Silent (SNP) | VAF 14/208 reads (7%) | catalogued as COSV99789463; called by muse, mutect2
- GANC | c.879G>A p.E293= | Silent (SNP) | VAF 9/149 reads (6%) | catalogued as COSV100530570, COSV100531271; called by muse, mutect2
- GPCPD1 | c.819T>G p.T273= | Silent (SNP) | VAF 32/178 reads (18%) | catalogued as COSV66830748; called by muse, mutect2, varscan2
- IFI16 | c.2040A>G p.S680= (on ENST00000295809 / NM_001364867.2; = p.S624= on NM_005531.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as COSV55533985; called by muse, mutect2, varscan2
- MAPKAPK3 | c.912C>T p.I304= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV63597457; called by muse, mutect2
- MORN1 | c.624C>G p.G208= | Silent (SNP) | VAF 11/50 reads (22%) | called by mutect2, varscan2
- MTOR | c.7215G>A p.E2405= | Silent (SNP) | VAF 8/138 reads (6%) | catalogued as COSV100815583; called by muse, mutect2
- MUC21 | c.1446C>A p.L482= | Silent (SNP) | VAF 46/223 reads (21%) | catalogued as COSV66220566, COSV66220846; called by muse, mutect2, varscan2
- NIN | c.1848A>G p.E616= | Silent (SNP) | VAF 21/144 reads (15%) | catalogued as COSV55390156; called by muse, mutect2, varscan2
- OBSL1 | c.1809C>T p.H603= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as rs768657041, COSV54719117; called by muse, mutect2, varscan2
- SON | c.1008G>T p.A336= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV51657711, COSV51669559; called by muse, mutect2, varscan2
- SRBD1 | c.690C>T p.A230= | Silent (SNP) | VAF 22/105 reads (21%) | catalogued as COSV55398680; called by muse, mutect2, varscan2
- SUPT7L | c.1035G>A p.E345= | Silent (SNP) | VAF 68/272 reads (25%) | catalogued as COSV53114724; called by muse, mutect2, varscan2
- TMC6 | c.2394G>A p.L798= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV56945208; called by muse, mutect2, varscan2
- TRPC4AP | c.954C>T p.F318= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as COSV52679797; called by muse, mutect2, varscan2
- DCHS2 | n.6075T>G | RNA (SNP) | VAF 37/184 reads (20%) | catalogued as COSV61772016; called by muse, mutect2, varscan2
- PLA2G4E | c.257-2250C>A | Intron (SNP) | VAF 4/37 reads (11%) | catalogued as COSV101268501; called by muse, mutect2
